Somatic mutation profile of tumor specimen TCGA-DD-A4NB-01A (aliquot TCGA-DD-A4NB-01A-12D-A25V-10) from TCGA case TCGA-DD-A4NB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, fibrolamellar; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 25.8 years (9,426 days).
Specimen TCGA-DD-A4NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45a95a21-189e-4791-9ac1-7522c3634967.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NB-11A (Solid Tissue Normal), aliquot TCGA-DD-A4NB-11A-11D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bc58200-298a-4bb4-974c-d485f03d743c

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, Frame Shift Del 5, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.3094C>A p.Q1032K | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs761830077, COSV55003234; called by muse, mutect2, varscan2
- BAG6 | c.1799C>T p.T600I (on ENST00000676571; = p.T553I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV52992942; called by muse, mutect2, varscan2
- FEZF2 | c.1113C>A p.H371Q | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51863540; called by muse, mutect2, varscan2
- FPGS | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64675936; called by muse, mutect2
- ITGA1 | c.1132T>C p.S378P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV50887520; called by muse, mutect2, varscan2
- KRAS | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55867748, COSV56172241, COSV99773308; called by muse, mutect2, varscan2
- MYH15 | c.1126T>C p.F376L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56314564; called by muse, mutect2, varscan2
- MYT1L | c.1699C>G p.R567G | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67725862; called by muse, mutect2
- PIGQ | c.2202del p.V735Sfs*34 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs750067878; called by mutect2, pindel, varscan2
- SCN3A | c.5822A>G p.K1941R | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV51816132; called by muse, mutect2, varscan2
- SYT16 | c.1001A>G p.D334G | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs776037610, COSV70857930; called by muse, mutect2, varscan2
- UNC79 | c.1915A>T p.N639Y (on ENST00000393151 / NM_001346218.2; = p.N462Y on NM_020818.5) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV56397781; called by muse, mutect2, varscan2
- ZNF426 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53468874, COSV53469912; called by muse, mutect2, varscan2
- ZNF585A | c.1087T>G p.F363V (on ENST00000292841 / NM_001288800.2; = p.F308V on NM_152655.3) | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53065445; called by muse, mutect2, varscan2
- ZNF841 | c.1552T>A p.F518I (on ENST00000426391 / NM_001369830.1; = p.F634I on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63470903; called by muse, mutect2
- AFF1 | c.1186_1189del p.S396Lfs*2 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- CASP8 | c.227_228insAG p.T77Vfs*4 | Frame Shift Ins (INS) | VAF 25/145 reads (17%) | called by mutect2, pindel, varscan2
- CHD1 | c.2455dup p.I819Nfs*33 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1391_1425del p.F464* | Frame Shift Del (DEL) | VAF 53/378 reads (14%) | called by mutect2, pindel
- MUC5B | c.5375_5376del p.E1792Vfs*3 | Frame Shift Del (DEL) | VAF 38/209 reads (18%) | called by pindel, varscan2
- NEUROD1 | c.703_715del p.D235Sfs*23 | Frame Shift Del (DEL) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- FOCAD | c.321C>T p.H107= | Silent (SNP) | VAF 49/206 reads (24%) | catalogued as COSV58103503; called by muse, mutect2, varscan2
- H2AC11 | c.42G>A p.K14= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs201354380, COSV60362339; called by muse, mutect2, varscan2
- MAP3K10 | c.366G>A p.V122= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1568485648, COSV53423710; called by muse, mutect2, varscan2
- MGAT4B | c.1212C>T p.S404= | Silent (SNP) | VAF 38/336 reads (11%) | catalogued as rs1196768513, COSV52978531; called by muse, mutect2, varscan2
- PLEKHG4B | c.1425C>T p.S475= (on ENST00000283426; = p.S831= on NM_052909.5) | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs868672086, COSV52050772; called by muse, mutect2, varscan2
- PTPRM | c.255C>T p.L85= | Silent (SNP) | VAF 34/138 reads (25%) | catalogued as rs1335866468, COSV59869775; called by muse, mutect2, varscan2
- SLC35F3 | c.240C>T p.I80= | Silent (SNP) | VAF 68/263 reads (26%) | catalogued as COSV64029529; called by muse, mutect2, varscan2
- UGT1A3 | c.231G>T p.L77= | Silent (SNP) | VAF 43/211 reads (20%) | catalogued as COSV59393224; called by muse, mutect2, varscan2
- ZNF83 | c.318A>G p.L106= | Silent (SNP) | VAF 26/209 reads (12%) | catalogued as rs778584351, COSV56531030; called by muse, mutect2, varscan2
- ACOT11 | c.-19T>C | 5'UTR (SNP) | VAF 43/240 reads (18%) | catalogued as COSV100650761; called by muse, mutect2, varscan2
- FUT9 | c.*6098T>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | catalogued as COSV100134114; called by muse, mutect2, varscan2
